Somatic mutation profile of tumor specimen TARGET-20-PATCBV-09A (aliquot TARGET-20-PATCBV-09A-01D) from TARGET case TARGET-20-PATCBV, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 14.6 years (5,339 days).
Specimen TARGET-20-PATCBV-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 77f678a0-c05f-4daf-b91e-bee6ee23e441.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PATCBV-14A (Bone Marrow Normal), aliquot TARGET-20-PATCBV-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1b3f4b00-4970-47eb-849a-6f5d615c06a5

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCND3 | c.811dup p.R271Pfs*53 | Frame Shift Ins (INS) | VAF 12/38 reads (32%) | called by mutect2, pindel, varscan2
- PIK3R5 | c.778G>A p.V260M | Missense Mutation (SNP) | VAF 37/66 reads (56%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
